Gene-level copy-number profile of tumor specimen TCGA-Q1-A6DW-01A from TCGA case TCGA-Q1-A6DW, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage I; Tumor grade: GX; Age at diagnosis: 44.4 years (16,200 days).
Specimen TCGA-Q1-A6DW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.51ac04d8-52fc-434c-861f-1dffa8e893b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Q1-A6DW-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0bcfa465-e139-4ca0-a889-614d49a70f15

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,543; copy number 2: 45,901; copy number 3: 7,779; copy number 4: 1,382; copy number 5: 1,706; copy number 6: 49; copy number 8: 460.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Q1-A6DW-01A-11D-A32H-01): tumor purity 0.74, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,215 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:104,063,039–198,222,513, 1,660 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–33,522,230, 509 genes, copy number 6–8 (broad region; genes not listed).
- chr7:122,318,411–122,886,759, 1 gene, copy number 5 (within-gene range 3–5): CADPS2.
- chr7:122,676,580–125,482,966, 43 genes, copy number 5: AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr20:14,547,184–14,636,524, 2 genes, copy number 5: RNF11P2, MACROD2-IT1.

Autosomal genes at a single copy (total copy number 1): 2,543. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
